CCDI case PBBWPP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bb190242-d579-44e7-a2e6-3e53f7331610

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.3 years (5,964 days).

Biospecimens (3 samples)
- Sample 0DJ4BZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJ4C5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DJ4CC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
